Somatic mutation profile of tumor specimen TCGA-DU-7299-01A (aliquot TCGA-DU-7299-01A-21D-2024-08) from TCGA case TCGA-DU-7299, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.6 years (12,266 days).
Specimen TCGA-DU-7299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d9fa977-eb55-49b5-a5df-ada09cc919e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7299-10A (Blood Derived Normal), aliquot TCGA-DU-7299-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1720d329-4d11-4561-bbbd-3fba529eff81

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Frame Shift Del 5, Silent 4, In Frame Del 2, Splice Region 1, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 35/43 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CHRM3 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs1173536206, COSV55107655; called by muse, mutect2
- CRISP2 | c.516T>C p.A172= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV59257230; called by muse, mutect2
- DNAH17 | c.4048G>A p.V1350M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs373436522; called by muse, mutect2, varscan2
- GPR162 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as rs368934487; called by muse, mutect2, varscan2
- MFHAS1 | c.3101C>T p.P1034L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as rs1477943630, COSV52287473, COSV52287581; called by muse, mutect2, varscan2
- MGAT3 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.541); catalogued as rs200726619, COSV57869030; called by muse, mutect2, varscan2
- MTIF2 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55054518; called by muse, mutect2, varscan2
- MYT1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | catalogued as COSV60515152; called by muse, mutect2, varscan2
- NF1 | c.4108del p.Q1370Rfs*8 (on ENST00000358273 / NM_001042492.3; = p.Q1370Rfs*15 on NM_000267.3) | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | catalogued as CM143397, COSV62214782; called by mutect2, pindel, varscan2
- OBSL1 | c.2441_2442del p.H814Rfs*16 | Frame Shift Del (DEL) | VAF 56/163 reads (34%) | catalogued as rs1267079237; called by mutect2, pindel, varscan2
- PHB2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs782039567, COSV54642573; called by muse, mutect2, varscan2
- PIK3R5 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs200317598, COSV52659348; called by muse, mutect2, varscan2
- RHOD | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs747533444, COSV58212123; called by muse, mutect2, varscan2
- SLC25A21 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1392165040, COSV58717920, COSV58733990; called by muse, mutect2, varscan2
- SNED1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.701); catalogued as rs1043639010, COSV60034693; called by muse, mutect2, varscan2
- ZNF138 | c.278C>T p.T93I (on ENST00000307355 / NM_001367572.1; = p.T67I on NM_006524.4) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs749460601, COSV56468288; called by muse, mutect2, varscan2
- BICRA | c.2911_2913del p.I971del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- CACNA1S | c.1445_1447del p.K482del | In Frame Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, pindel, varscan2
- NF1 | c.1393_1394del p.X465_splice | Splice Site (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- PCDH9 | c.908_909del p.F303Cfs*4 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | called by mutect2, pindel, varscan2
- RERE | c.157_158del p.S53* | Frame Shift Del (DEL) | VAF 94/434 reads (22%) | called by pindel, varscan2
- ZC3H7A | c.948_949del p.P317* | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by pindel, varscan2
- GALE | c.285C>T p.G95= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs200029591, COSV52526911, COSV52527621; called by muse, mutect2, varscan2
- PCDHA3 | c.1125C>T p.S375= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV63545873; called by muse, mutect2
- PRKAR1B | c.18C>G p.A6= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV64320267; called by muse, mutect2, varscan2
- VPS72 | c.312G>A p.P104= | Silent (SNP) | VAF 19/240 reads (8%) | catalogued as rs752210930, COSV63166765, COSV63166797; called by muse, mutect2
- SSPOP | n.5789G>A | RNA (SNP) | VAF 36/93 reads (39%) | catalogued as COSV100022499, COSV50487063; called by muse, mutect2, varscan2
